Somatic mutation profile of tumor specimen 8c73f3a5-fea8-4942-90c0-966f66 (aliquot 8c73f3a5-fea8-4942-90c0-966f66_D6_2) from CPTAC case 11CO061, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen 8c73f3a5-fea8-4942-90c0-966f66: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f077fc00-9db3-4ebd-b7d3-5a72ba419155.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 127d1942-2f41-4487-9c09-702e20 (Blood Derived Normal), aliquot 127d1942-2f41-4487-9c09-702e20_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3278c4c9-37a5-4cb9-8156-f08be2a69468

The open-access MAF lists 929 somatic variants for this specimen: 655 protein-altering or splice-affecting, 160 silent, 114 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 445, Silent 160, Frame Shift Ins 86, Frame Shift Del 82, Intron 66, 3'UTR 15, Splice Region 13, Splice Site 12, 5'UTR 11, Nonsense Mutation 10, RNA 10, 5'Flank 6.

Variants (750 of 929; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.1961del p.K654Sfs*47 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | catalogued as rs80357522, CD076746, CD951610; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by mutect2, varscan2
- COL11A2 | c.966dup p.T323Hfs*19 | Frame Shift Ins (INS) | VAF 26/163 reads (16%) | catalogued as rs748440351; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 15/112 reads (13%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- PMS2 | c.2275+2T>C p.X759_splice | Splice Site (SNP) | VAF 15/126 reads (12%) | catalogued as rs1562604682; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SLC17A5 | c.406A>G p.K136E | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs80338795, CM003476, COSV63288151; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.1889C>T p.A630V | Missense Mutation (SNP) | VAF 151/1113 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs544333323, COSV55113682; called by muse, mutect2, varscan2
- ABHD16B | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 95/596 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs762160637; called by muse, mutect2, varscan2
- ABRAXAS1 | c.864dup p.P289Sfs*4 | Frame Shift Ins (INS) | VAF 10/46 reads (22%) | catalogued as rs35378950; called by mutect2, pindel, varscan2
- ACADSB | c.187A>G p.M63V | Missense Mutation (SNP) | VAF 8/253 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as rs1311840961; called by muse, mutect2
- ACE | c.1105A>G p.R369G | Missense Mutation (SNP) | VAF 52/317 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.146); catalogued as rs373357172; called by muse, mutect2, varscan2
- ACP5 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 54/390 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.226); catalogued as rs149133430; called by muse, mutect2, varscan2
- ACTA1 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 109/615 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.985); catalogued as COSV100796798; called by muse, mutect2, varscan2
- ACTR1A | c.436A>G p.S146G | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs981170792; called by muse, mutect2, varscan2
- ACTR5 | c.1296C>T p.P432= | Splice Region (SNP) | VAF 14/58 reads (24%) | catalogued as rs1230434763; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ACY3 | c.497A>G p.N166S | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV54830037; called by muse, mutect2, varscan2
- ADAM9 | c.833G>A p.G278D | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as rs1465967321; called by muse, mutect2, varscan2
- ADAMTS14 | c.1276G>A p.A426T | Missense Mutation (SNP) | VAF 33/267 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs745659747, COSV64603916; called by muse, mutect2, varscan2
- ADAMTS20 | c.1603G>A p.G535S | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as rs778375054; called by muse, mutect2, varscan2
- ADAT3 | c.485G>A p.W162* | Nonsense Mutation (SNP) | VAF 26/108 reads (24%) | catalogued as rs1390223407; called by muse, mutect2, varscan2
- ADCY5 | c.1888G>A p.A630T | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs200831250, COSV59200864; called by muse, mutect2, varscan2
- AHDC1 | c.3551G>A p.R1184H | Missense Mutation (SNP) | VAF 64/461 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as rs547656373; called by muse, mutect2, varscan2
- AHDC1 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.034); catalogued as rs748078811, COSV99899807; called by muse, mutect2, varscan2
- AL136295.1 | c.1489A>G p.N497D | Missense Mutation (SNP) | VAF 41/300 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.579); catalogued as rs1234647932; called by muse, mutect2, varscan2
- ANKFN1 | c.3712C>T p.R1238C (on ENST00000653862; = p.R1091C on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/570 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as rs1424150720; called by muse, mutect2
- ANKRD20A4P | c.2225C>T p.A742V | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs752399148; called by muse, mutect2, varscan2
- APBB2 | c.1958G>A p.R653H (on ENST00000295974 / NM_001166050.2; = p.R654H on NM_004307.2) | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99922913; called by muse, mutect2, varscan2
- ARHGAP5 | c.2676del p.F892Lfs*9 | Frame Shift Del (DEL) | VAF 12/120 reads (10%) | catalogued as rs781483073; called by mutect2, pindel, varscan2
- ARHGEF40 | c.3901A>G p.S1301G | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1281498849; called by muse, mutect2, varscan2
- ARID1B | c.788T>C p.M263T | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as rs1413303563; called by muse, mutect2, varscan2
- ARID2 | c.5239G>T p.G1747* | Nonsense Mutation (SNP) | VAF 5/56 reads (9%) | catalogued as COSV57600337; called by muse, mutect2
- ARID5B | c.2434A>G p.K812E | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs752194887; called by muse, mutect2, varscan2
- ARMCX2 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 38/306 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as rs1556060599; called by muse, mutect2, varscan2
- ATN1 | c.2699G>A p.R900H | Missense Mutation (SNP) | VAF 22/570 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.028); catalogued as COSV100756001; called by muse, mutect2
- ATXN2L | c.2997del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 10/67 reads (15%) | catalogued as rs1288664341; called by mutect2, pindel, varscan2
- AXIN2 | c.1925dup p.A643Gfs*64 | Frame Shift Ins (INS) | VAF 25/208 reads (12%) | catalogued as rs1301294410; called by mutect2, pindel, varscan2
- BAP1 | c.2098C>T p.R700W | Missense Mutation (SNP) | VAF 105/674 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs1284965361, COSV99964338; called by muse, mutect2, varscan2
- BFSP2 | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 94/548 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.05); catalogued as COSV56589111; called by muse, mutect2, varscan2
- BLMH | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1382347908; called by muse, mutect2, varscan2
- BMP1 | c.1839dup p.N614Qfs*21 | Frame Shift Ins (INS) | VAF 27/205 reads (13%) | catalogued as rs758822270; called by mutect2, varscan2
- BRSK1 | c.1135dup p.R379Pfs*54 | Frame Shift Ins (INS) | VAF 18/68 reads (26%) | catalogued as rs746043904; called by mutect2, varscan2
- BSG | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs374628867; called by muse, varscan2
- BSN | c.6748dup p.R2250Pfs*17 | Frame Shift Ins (INS) | VAF 41/357 reads (11%) | catalogued as rs1335477411; called by mutect2, pindel, varscan2
- BTBD11 | c.1682C>T p.A561V (on ENST00000280758 / NM_001018072.2; = p.A98V on NM_001017523.2) | Missense Mutation (SNP) | VAF 43/209 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1368588123, COSV55016681; called by muse, mutect2, varscan2
- BTBD18 | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 61/353 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs771179268; called by muse, mutect2, varscan2
- C15orf39 | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746334151; called by muse, mutect2, varscan2
- C2CD4D | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 36/295 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs867420102; called by muse, mutect2, varscan2
- CACNA1C | c.1273C>T p.R425W | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59726560; called by muse, mutect2, varscan2
- CACNB3 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as rs774926593; called by muse, mutect2, varscan2
- CADPS | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 38/340 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200699296, COSV51871986; called by muse, mutect2, varscan2
- CARS2 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 42/277 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as rs547702190; called by muse, mutect2, varscan2
- CBLC | c.1332dup p.R445Qfs*55 | Frame Shift Ins (INS) | VAF 11/93 reads (12%) | catalogued as rs766555920; called by mutect2, pindel, varscan2
- CBWD6 | c.613A>G p.T205A | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.826); catalogued as rs777525282; called by muse, mutect2, varscan2
- CCAR2 | c.1249dup p.R417Pfs*49 | Frame Shift Ins (INS) | VAF 32/98 reads (33%) | catalogued as rs756536005; called by mutect2, varscan2
- CCDC152 | c.671del p.N224Tfs*14 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as rs920626028; called by mutect2, pindel, varscan2
- CCDC153 | c.599del p.P200Lfs*4 | Frame Shift Del (DEL) | VAF 18/153 reads (12%) | catalogued as rs745729530; called by mutect2, pindel, varscan2
- CCDC24 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1181157072; called by muse, mutect2, varscan2
- CCNQ | c.212T>C p.L71P | Missense Mutation (SNP) | VAF 44/399 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52346008; called by muse, mutect2, varscan2
- CCR8 | c.977T>C p.L326P | Missense Mutation (SNP) | VAF 9/195 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as COSV58337328; called by muse, mutect2
- CDAN1 | c.3099C>T p.D1033= | Splice Region (SNP) | VAF 27/261 reads (10%) | catalogued as rs148832555; called by muse, mutect2, varscan2
- CELA2B | c.775_777del p.N259del | In Frame Del (DEL) | VAF 27/231 reads (12%) | catalogued as rs761215684; called by mutect2, pindel, varscan2
- CGAS | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as rs190867294, COSV64807915; called by muse, mutect2, varscan2
- CHD4 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 52/324 reads (16%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.006); catalogued as COSV58897793; called by muse, varscan2
- CHL1 | c.1409G>A p.R470Q (on ENST00000397491 / NM_001253387.1; = p.R486Q on NM_006614.4) | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.751); catalogued as rs185238679; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 13/97 reads (13%) | catalogued as rs751548647; called by mutect2, varscan2
- CLUH | c.1324dup p.D442Gfs*99 (on ENST00000435359; = p.D480Gfs*99 on NM_015229.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 71/300 reads (24%) | catalogued as rs752224729; called by mutect2, varscan2
- CNGA4 | c.1445C>T p.A482V | Missense Mutation (SNP) | VAF 67/450 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as rs770886002, COSV66005683; called by muse, mutect2, varscan2
- COIL | c.587del p.K196Rfs*13 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | catalogued as rs748995811; called by mutect2, varscan2
- COL24A1 | c.3807del p.G1270Efs*68 | Frame Shift Del (DEL) | VAF 4/31 reads (13%) | catalogued as rs751232308; called by mutect2, pindel, varscan2
- COL5A1 | c.4050dup p.G1351Rfs*14 | Frame Shift Ins (INS) | VAF 43/288 reads (15%) | catalogued as rs758337699; called by mutect2, varscan2
- COP1 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1373217036, COSV58165408; called by muse, mutect2, varscan2
- CPT2 | c.1892G>A p.R631H | Missense Mutation (SNP) | VAF 39/228 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.264); catalogued as rs1009503062, COSV53758763; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRAT | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs775390429; called by muse, mutect2, varscan2
- CRTC1 | c.1277dup p.E427Rfs*24 | Frame Shift Ins (INS) | VAF 26/164 reads (16%) | catalogued as rs760791352; called by mutect2, varscan2
- CST1 | c.241del p.V81* | Frame Shift Del (DEL) | VAF 40/332 reads (12%) | catalogued as rs756924682; called by mutect2, varscan2
- CTBP1 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 42/255 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.527); catalogued as COSV52072341; called by muse, mutect2, varscan2
- CYP7A1 | c.1182G>A p.M394I | Missense Mutation (SNP) | VAF 47/210 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs750037867; called by mutect2, varscan2
- DCAF1 | c.4336G>A p.A1446T | Missense Mutation (SNP) | VAF 37/264 reads (14%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as rs372451907, COSV60041116; called by muse, mutect2, varscan2
- DDAH2 | c.177G>T p.Q59H | Missense Mutation (SNP) | VAF 24/649 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV65384447; called by muse, mutect2
- DDR1 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.909); catalogued as rs766265850, COSV61327647; called by muse, mutect2, varscan2
- DISP3 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV53826074; called by muse, mutect2, varscan2
- DMRTC2 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.813); catalogued as rs782716976, COSV54185770; called by muse, mutect2, varscan2
- DNAH7 | c.11996C>T p.A3999V | Missense Mutation (SNP) | VAF 29/270 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.826); catalogued as COSV100414094; called by muse, mutect2, varscan2
- DNAI2 | c.1052C>T p.T351M | Missense Mutation (SNP) | VAF 55/321 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs548988225; called by muse, mutect2, varscan2
- DNER | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs746678134, COSV59179959; called by muse, varscan2
- DNMT1 | c.387dup p.K130Qfs*19 | Frame Shift Ins (INS) | VAF 26/207 reads (13%) | catalogued as rs755889652; called by mutect2, varscan2
- DOCK3 | c.1447A>G p.N483D | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56547593; called by muse, mutect2, varscan2
- DTL | c.2039C>T p.P680L | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.356); catalogued as rs753383449, COSV65342402, COSV65342415; called by muse, mutect2, varscan2
- E2F1 | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 53/486 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58535777; called by muse, mutect2, varscan2
- EPHB6 | c.165+1dup | Frame Shift Ins (INS) | VAF 120/408 reads (29%) | catalogued as rs771807343; called by mutect2, varscan2
- ERVV-2 | c.788del p.N263Ifs*11 | Frame Shift Del (DEL) | VAF 45/203 reads (22%) | catalogued as rs1462590370; called by mutect2, pindel, varscan2
- EXOSC5 | c.148+2T>C p.X50_splice | Splice Site (SNP) | VAF 19/130 reads (15%) | catalogued as rs754549129; called by muse, mutect2, varscan2
- F2RL1 | c.890T>C p.L297P | Missense Mutation (SNP) | VAF 39/236 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56996316; called by muse, mutect2, varscan2
- FAM131B | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 73/276 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.823); catalogued as rs757750227, COSV68125404; called by muse, mutect2, varscan2
- FAM205A | c.1392dup p.K466Efs*8 | Frame Shift Ins (INS) | VAF 21/157 reads (13%) | catalogued as rs760731345; called by mutect2, pindel, varscan2
- FAN1 | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367829539; called by muse, mutect2, varscan2
- FASTKD5 | c.2000dup p.F668Lfs*8 | Frame Shift Ins (INS) | VAF 26/244 reads (11%) | catalogued as rs1233549844; called by mutect2, pindel
- FAU | c.292A>G p.K98E | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs1200469527; called by muse, mutect2, varscan2
- FBXL16 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.647); catalogued as rs757114798, COSV60965335; called by muse, mutect2, varscan2
- FBXL7 | c.1177G>A p.G393S | Missense Mutation (SNP) | VAF 54/604 reads (9%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.503); catalogued as rs760945887, COSV100309088, COSV61649297; called by muse, mutect2
- FBXO4 | c.692T>C p.F231S | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV99715147; called by muse, mutect2, varscan2
- FBXO43 | c.377del p.K126Rfs*33 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | catalogued as rs1406026740; called by mutect2, pindel, varscan2
- FGF19 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 50/436 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53736953; called by muse, mutect2, varscan2
- FIGNL1 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs377263544, COSV63553210; called by muse, mutect2, varscan2
- FLNC | c.2972G>A p.R991Q | Missense Mutation (SNP) | VAF 277/1057 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.041); catalogued as rs762995952, COSV104395946; called by muse, mutect2, varscan2
- FOXN3 | c.287del p.P96Hfs*42 | Frame Shift Del (DEL) | VAF 15/138 reads (11%) | catalogued as rs760347049; called by mutect2, varscan2
- FREM2 | c.2102C>T p.P701L | Missense Mutation (SNP) | VAF 60/333 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs777945148, COSV54836332; called by muse, mutect2, varscan2
- FTHL17 | c.538G>A p.V180I | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs1412262062, COSV100784251; called by muse, mutect2, varscan2
- GATD1 | c.379G>A p.G127S | Missense Mutation (SNP) | VAF 44/252 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs202087022; called by muse, mutect2, varscan2
- GET3 | c.982dup p.A328Gfs*90 | Frame Shift Ins (INS) | VAF 29/250 reads (12%) | catalogued as rs763284415; called by mutect2, pindel, varscan2
- GIGYF1 | c.1676C>T p.A559V | Missense Mutation (SNP) | VAF 39/313 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.228); catalogued as rs200730732; called by muse, mutect2, varscan2
- GIPC1 | c.149del p.P50Lfs*48 | Frame Shift Del (DEL) | VAF 38/118 reads (32%) | catalogued as rs771881138; called by mutect2, varscan2
- GLMP | c.878del p.G293Afs*17 | Frame Shift Del (DEL) | VAF 49/301 reads (16%) | catalogued as rs1490438727; called by mutect2, pindel, varscan2
- GLUD1 | c.865T>C p.Y289H | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV53281561; called by muse, mutect2
- GNAS | c.1747G>T p.D583Y | Missense Mutation (SNP) | VAF 23/432 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.237); catalogued as COSV58331147; called by muse, mutect2
- GOT1 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs772704095, COSV65147316; called by muse, mutect2, varscan2
- GRM1 | c.2795C>T p.P932L | Missense Mutation (SNP) | VAF 32/630 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.593); catalogued as COSV99269085; called by muse, mutect2
- HDGFL1 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as rs1393308072, COSV57752370; called by muse, mutect2, varscan2
- HECA | c.1004dup p.H336Tfs*25 | Frame Shift Ins (INS) | VAF 31/260 reads (12%) | catalogued as rs771658394; called by mutect2, varscan2
- HECTD4 | c.5398G>A p.A1800T | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as rs1178472325; called by muse, mutect2, varscan2
- HELZ2 | c.6616dup p.R2206Pfs*42 (on ENST00000467148 / NM_001037335.2; = p.R1637Pfs*42 on NM_033405.3) | Frame Shift Ins (INS) | VAF 28/176 reads (16%) | catalogued as rs745497383; called by mutect2, varscan2
- HELZ2 | c.4832G>A p.R1611H (on ENST00000467148 / NM_001037335.2; = p.R1042H on NM_033405.3) | Missense Mutation (SNP) | VAF 39/434 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.01); catalogued as rs779686338, COSV71296971; called by muse, mutect2
- HLA-DOB | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 38/293 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763626572, COSV71271024; called by muse, mutect2, varscan2
- HOXB3 | c.773dup p.S260Ifs*37 | Frame Shift Ins (INS) | VAF 29/232 reads (13%) | catalogued as rs766032924; called by mutect2, pindel, varscan2
- HOXD1 | c.61C>T p.L21F | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as rs747893605; called by muse, mutect2, varscan2
- HPS4 | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 60/488 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs747080557; called by muse, mutect2, varscan2
- HTRA1 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as CM153334, COSV64564034; called by muse, mutect2, varscan2
- IGSF10 | c.1967del p.L656* | Frame Shift Del (DEL) | VAF 20/174 reads (11%) | catalogued as rs1560178211; called by mutect2, pindel, varscan2
- IGSF9 | c.154dup p.L52Pfs*27 | Frame Shift Ins (INS) | VAF 14/126 reads (11%) | catalogued as rs753928344; called by mutect2, varscan2
- IKBKB | c.1816C>T p.R606* | Nonsense Mutation (SNP) | VAF 37/136 reads (27%) | catalogued as rs768351634; called by muse, mutect2, varscan2
- IL13RA2 | c.713C>A p.P238H | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54563859; called by muse, mutect2, varscan2
- IL17RA | c.382A>G p.R128G | Missense Mutation (SNP) | VAF 58/632 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV60053652; called by muse, mutect2
- INTS13 | c.1352A>G p.Q451R | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (1); PolyPhen probably damaging (0.982); catalogued as rs1451069976; called by muse, mutect2
- IPO9 | c.2675A>C p.D892A | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV64233609; called by muse, mutect2, varscan2
- JUP | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 48/356 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as rs1433432540, COSV60277127; called by muse, mutect2, varscan2
- KCNB2 | c.435del p.E146Nfs*3 | Frame Shift Del (DEL) | VAF 19/131 reads (15%) | catalogued as rs752059864; called by mutect2, varscan2
- KCNG2 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as rs781639985; called by muse, mutect2, varscan2
- KCNQ5 | c.2602A>G p.K868E | Missense Mutation (SNP) | VAF 34/279 reads (12%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.003); catalogued as rs780494716; called by muse, mutect2, varscan2
- KCNS3 | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 30/292 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as rs775574102, COSV58406156; called by muse, mutect2, varscan2
- KCNV2 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 50/386 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as rs769810672, COSV101172661; called by muse, mutect2, varscan2
- KHNYN | c.1990C>T p.R664W | Missense Mutation (SNP) | VAF 32/231 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs778019188; called by muse, mutect2, varscan2
- KLHL34 | c.861dup p.R288Afs*9 | Frame Shift Ins (INS) | VAF 35/225 reads (16%) | catalogued as rs762518653; called by mutect2, varscan2
- KMT2B | c.3446G>A p.G1149D | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV99720012; called by muse, mutect2
- KMT2C | c.8525del p.N2842Mfs*21 | Frame Shift Del (DEL) | VAF 10/100 reads (10%) | catalogued as rs1248944002; called by pindel, varscan2
- KMT5C | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 44/243 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.717); catalogued as rs748471535, COSV55319611; called by muse, mutect2, varscan2
- KNOP1 | c.957del p.G320Afs*8 | Frame Shift Del (DEL) | VAF 16/142 reads (11%) | catalogued as rs759734033, COSV54927684; called by mutect2, varscan2
- KPRP | c.799del p.R267Afs*19 | Frame Shift Del (DEL) | VAF 27/258 reads (10%) | catalogued as COSV100908740; called by mutect2, pindel, varscan2
- LARGE1 | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 60/503 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746251069, COSV61665276; called by muse, mutect2, varscan2
- LENG8 | c.2138G>A p.R713H | Missense Mutation (SNP) | VAF 53/387 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1336995934, COSV58730984; called by muse, mutect2, varscan2
- LMNB2 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 66/385 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as rs761255813; called by muse, mutect2, varscan2
- LONP1 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 45/218 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.493); catalogued as rs199803800; called by muse, mutect2, varscan2
- LRCH3 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as rs754369527, COSV100605026; called by muse, mutect2, varscan2
- LTA | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 28/245 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs566451995; called by muse, mutect2, varscan2
- LY6L | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 19/199 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.242); catalogued as rs371591060; called by muse, mutect2
- LY96 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.03); catalogued as rs1003205319, COSV53026404, COSV99514381; called by muse, mutect2, varscan2
- MACF1 | c.12064G>A p.V4022M (on ENST00000372915; = p.V1955M on NM_012090.5) | Missense Mutation (SNP) | VAF 17/171 reads (10%) | catalogued as rs767102316; called by muse, mutect2
- MAGEC3 | c.1451C>T p.T484M | Missense Mutation (SNP) | VAF 25/320 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.136); catalogued as rs1453607034, COSV53581522; called by muse, mutect2
- MAPK8IP3 | c.2129C>T p.A710V | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1228038251; called by muse, mutect2, varscan2
- MATK | c.1067G>A p.R356H (on ENST00000310132 / NM_139355.3; = p.R357H on NM_002378.4) | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59554696; called by muse, mutect2, varscan2
- MBD6 | c.2345del p.G782Efs*13 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | catalogued as rs746267361; called by mutect2, varscan2
- MGLL | c.482T>C p.V161A (on ENST00000398104 / NM_001003794.2; = p.V171A on NM_007283.6) | Missense Mutation (SNP) | VAF 16/456 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as rs1559914001; called by muse, mutect2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 6/62 reads (10%) | catalogued as rs762448666; called by mutect2, pindel
- MMP24 | c.1690C>T p.R564C | Missense Mutation (SNP) | VAF 35/256 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs747017137, COSV55768428; called by muse, mutect2, varscan2
- MMRN1 | c.1169T>C p.I390T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs764309603; called by mutect2, varscan2
- MRPL28 | c.23T>C p.V8A | Missense Mutation (SNP) | VAF 16/296 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.073); catalogued as rs1467945704; called by muse, mutect2
- MSL1 | c.359_364del p.A120_A121del | In Frame Del (DEL) | VAF 20/85 reads (24%) | catalogued as rs1004486585; called by mutect2, pindel, varscan2
- MTCL1 | c.3339T>G p.I1113M (on ENST00000306329 / NM_001378206.1; = p.I794M on NM_015210.4) | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs1287323124; called by muse, mutect2, varscan2
- MTHFD1 | c.1670G>A p.R557Q | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs761445961; called by muse, mutect2, varscan2
- MYH7 | c.2108G>A p.R703H | Missense Mutation (SNP) | VAF 17/489 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs1232358310, CM1411007, COSV62516516; called by muse, mutect2
- MYO9B | c.2373+12_2373+13del | Splice Region (DEL) | VAF 6/23 reads (26%) | catalogued as rs747998041; called by mutect2, varscan2
- NME1-NME2 | c.683G>A p.R228Q (on ENST00000555572; = p.R203Q on NM_001018136.3) | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs777392074, COSV64510524; called by muse, mutect2, varscan2
- NNMT | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 59/342 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as rs777589054, COSV100248877; called by muse, mutect2, varscan2
- NR4A2 | c.325dup p.Q109Pfs*3 | Frame Shift Ins (INS) | VAF 63/467 reads (13%) | catalogued as rs774629025; called by mutect2, varscan2
- NXPE1 | c.566C>T p.A189V (on ENST00000424269; = p.A47V on NM_152315.5) | Missense Mutation (SNP) | VAF 67/480 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs760378519, COSV52627100; called by muse, mutect2, varscan2
- NXPH2 | c.493A>G p.K165E | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1254082087; called by muse, mutect2
- OR5H1 | c.764T>C p.L255P | Missense Mutation (SNP) | VAF 27/248 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs931923007; called by muse, mutect2, varscan2
- OR6C4 | c.303dup p.A102Cfs*18 | Frame Shift Ins (INS) | VAF 26/148 reads (18%) | catalogued as rs759108361; called by mutect2, varscan2
- OR8H2 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 30/306 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as COSV57944420, COSV57946768; called by muse, mutect2
- PASK | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 48/354 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.192); catalogued as rs755400071, COSV99300040; called by muse, mutect2, varscan2
- PCDHA13 | c.2056G>A p.A686T | Missense Mutation (SNP) | VAF 79/559 reads (14%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.006); catalogued as COSV56525028; called by muse, mutect2, varscan2
- PCDHA3 | c.596del p.N199Ifs*2 | Frame Shift Del (DEL) | VAF 10/72 reads (14%) | catalogued as rs782411180, COSV65371489; called by mutect2, varscan2
- PCDHA4 | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 163/1175 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.12); catalogued as COSV63543187; called by muse, mutect2, varscan2
- PCDHA6 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 139/1036 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.94); catalogued as COSV65343947; called by muse, mutect2, varscan2
- PCDHA7 | c.1169C>T p.T390M | Missense Mutation (SNP) | VAF 91/688 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.277); catalogued as rs550090383, COSV65346004; called by muse, mutect2, varscan2
- PCDHB15 | c.935T>C p.M312T | Missense Mutation (SNP) | VAF 27/244 reads (11%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs782191076; called by muse, mutect2, varscan2
- PCLO | c.15188A>G p.K5063R | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs756125419; called by muse, mutect2, varscan2
- PCMTD2 | c.1001dup p.V335Sfs*37 | Frame Shift Ins (INS) | VAF 10/76 reads (13%) | catalogued as rs1442840961; called by mutect2, pindel
- PCOLCE2 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.564); catalogued as rs375192412; called by muse, mutect2
- PDLIM5 | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 39/294 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs752012659; called by muse, mutect2, varscan2
- PDZD7 | c.1981C>T p.R661C | Missense Mutation (SNP) | VAF 40/262 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1440496362; called by muse, mutect2, varscan2
- PEX6 | c.2663G>A p.R888H | Missense Mutation (SNP) | VAF 64/532 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as rs267608247, CM100019; called by muse, mutect2, varscan2
- PIK3R1 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as rs765008592, COSV57124539; called by muse, mutect2, varscan2
- PKD1L3 | c.4714C>T p.R1572C | Missense Mutation (SNP) | VAF 57/356 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as rs748613965; called by muse, mutect2, varscan2
- PKDREJ | c.6263G>A p.G2088D | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53552847; called by muse, mutect2, varscan2
- PLAUR | c.29T>C p.L10P | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV55390897; called by mutect2, varscan2
- PLCG2 | c.1759C>T p.R587W | Missense Mutation (SNP) | VAF 47/421 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1049453423; called by muse, mutect2, varscan2
- PLD2 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 24/308 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs369078162; called by muse, mutect2
- PLEC | c.10538G>A p.R3513H (on ENST00000322810 / NM_201380.4; = p.R3403H on NM_000445.5) | Missense Mutation (SNP) | VAF 60/247 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.616); catalogued as rs781908703, COSV100517719; called by muse, mutect2, varscan2
- PLXNA4 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 86/418 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs149257060, COSV58103872, COSV58133382; called by muse, mutect2, varscan2
- PM20D1 | c.1301A>T p.N434I | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV65649303; called by muse, mutect2
- POLR2M | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs749550237; called by muse, mutect2
- PON2 | c.195dup p.S66* | Frame Shift Ins (INS) | VAF 20/128 reads (16%) | catalogued as rs1201102139; called by mutect2, varscan2
- PPFIA4 | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs746900406; called by muse, mutect2, varscan2
- PPM1D | c.1535dup p.N512Kfs*16 | Frame Shift Ins (INS) | VAF 14/100 reads (14%) | catalogued as rs763475304; called by mutect2, varscan2
- PPP1R42 | c.551A>G p.K184R | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as rs1242196328; called by mutect2, varscan2
- PRPF8 | c.3343A>G p.T1115A | Missense Mutation (SNP) | VAF 77/592 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.265); catalogued as COSV100517145; called by muse, mutect2, varscan2
- PSD4 | c.1919G>A p.R640Q | Missense Mutation (SNP) | VAF 45/280 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762095862, COSV55527744; called by muse, mutect2, varscan2
- PYM1 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1224536171, COSV56811420; called by muse, mutect2, varscan2
- RANBP9 | c.1939del p.M647Cfs*2 | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | catalogued as rs751504188; called by mutect2, pindel, varscan2
- RBM12 | c.1676A>G p.D559G | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); catalogued as rs1431186961; called by muse, mutect2, varscan2
- RBM14 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 8/209 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV59557741; called by muse, mutect2
- REM1 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 79/586 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199660041, COSV52427586; called by muse, varscan2
- RILPL1 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as rs1354591946; called by muse, mutect2
- RIMBP2 | c.2858C>T p.S953L | Missense Mutation (SNP) | VAF 43/259 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as rs764240295, COSV55464079; called by muse, mutect2, varscan2
- RNF128 | c.648del p.F216Lfs*32 (on ENST00000255499 / NM_194463.2; = p.F190Lfs*32 on NM_024539.3) | Frame Shift Del (DEL) | VAF 13/73 reads (18%) | catalogued as rs746331232, COSV55251573; called by mutect2, pindel, varscan2
- RNF31 | c.2681G>A p.R894H | Missense Mutation (SNP) | VAF 31/203 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs899095411, COSV60725760; called by muse, mutect2, varscan2
- RNPEPL1 | c.1810C>T p.R604C | Missense Mutation (SNP) | VAF 90/588 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1357808791, COSV54372757, COSV54373075; called by muse, mutect2, varscan2
- RPGRIP1 | c.164A>G p.E55G | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs754849037; called by mutect2, varscan2
- RPS18 | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as rs1468210462; called by muse, mutect2, varscan2
- RYR1 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 36/220 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.443); catalogued as COSV100615780; called by muse, mutect2, varscan2
- RYR1 | c.5180G>A p.R1727H | Missense Mutation (SNP) | VAF 90/754 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as rs774500412; called by muse, mutect2, varscan2
- SATB2 | c.1733C>T p.P578L | Missense Mutation (SNP) | VAF 57/400 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.285); catalogued as rs1160832366; called by muse, mutect2, varscan2
- SCAI | c.710C>T p.A237V (on ENST00000336505 / NM_001144877.3; = p.A260V on NM_173690.5) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as rs373639867; called by mutect2, varscan2
- SEC31B | c.269G>A p.G90D | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs755362315; called by muse, mutect2, varscan2
- SEL1L | c.2255C>T p.A752V | Missense Mutation (SNP) | VAF 39/302 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.107); catalogued as rs141918133; called by muse, mutect2, varscan2
- SEMA3E | c.220G>A p.G74S | Missense Mutation (SNP) | VAF 42/214 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs1285951013; called by muse, mutect2, varscan2
- SEPHS1 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 15/178 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as rs752102842, COSV100525807; called by muse, mutect2
- SETBP1 | c.4054G>A p.E1352K | Missense Mutation (SNP) | VAF 31/303 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.669); catalogued as rs146222882; called by muse, mutect2, varscan2
- SFI1 | c.2774G>A p.R925H (on ENST00000400288 / NM_001007467.3; = p.R894H on NM_014775.4) | Missense Mutation (SNP) | VAF 41/276 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs1256913842, COSV56716014; called by muse, mutect2, varscan2
- SH3PXD2B | c.2714A>G p.N905S | Missense Mutation (SNP) | VAF 36/241 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs774402005; called by muse, mutect2, varscan2
- SH3RF3 | c.1575G>A p.R525= | Splice Region (SNP) | VAF 16/251 reads (6%) | catalogued as COSV58693727; called by muse, mutect2
- SH3RF3 | c.1775T>C p.L592P | Missense Mutation (SNP) | VAF 42/399 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs1004348921; called by muse, mutect2, varscan2
- SHANK2 | c.3266G>A p.R1089H | Missense Mutation (SNP) | VAF 87/604 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781863842, COSV53606387; called by muse, mutect2, varscan2
- SHPRH | c.495del p.E166Nfs*3 | Frame Shift Del (DEL) | VAF 14/94 reads (15%) | catalogued as rs1469942319; called by mutect2, varscan2
- SIN3B | c.3476C>T p.P1159L | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.173); catalogued as rs762876758; called by muse, mutect2, varscan2
- SLC12A3 | c.1950del p.N653Tfs*19 | Frame Shift Del (DEL) | VAF 33/263 reads (13%) | catalogued as COSV52635287, COSV99344604; called by mutect2, pindel, varscan2
- SLC12A5 | c.2239C>T p.R747W (on ENST00000454036 / NM_001134771.2; = p.R724W on NM_020708.5) | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs532191036; called by muse, mutect2, varscan2
- SLC15A3 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs772096483, COSV57171276; called by muse, mutect2, varscan2
- SLC25A52 | c.166G>A p.A56T (on ENST00000672005; = p.A46T on NM_001034172.4) | Missense Mutation (SNP) | VAF 31/214 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs139162190; called by muse, mutect2, varscan2
- SLC35G2 | c.192del p.R66Efs*18 | Frame Shift Del (DEL) | VAF 16/118 reads (14%) | catalogued as rs750825208; called by mutect2, varscan2
- SLC35G3 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 39/321 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs534023886; called by muse, mutect2, varscan2
- SLC8B1 | c.1570G>A p.G524R | Missense Mutation (SNP) | VAF 40/382 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.965); catalogued as rs374615156, COSV99176713; called by muse, mutect2, varscan2
- SLFNL1 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 29/231 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs758903507; called by muse, mutect2, varscan2
- SMYD4 | c.1103C>T p.T368M | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs747374564; called by muse, mutect2, varscan2
- SOGA1 | c.4837G>A p.A1613T | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.352); catalogued as rs773140621; called by muse, mutect2, varscan2
- SOX7 | c.769del p.L257Wfs*14 | Frame Shift Del (DEL) | VAF 10/93 reads (11%) | catalogued as rs1478777952; called by mutect2, pindel, varscan2
- SOX9 | c.916del p.V306Cfs*77 | Frame Shift Del (DEL) | VAF 27/225 reads (12%) | catalogued as rs1297203260; called by mutect2, pindel, varscan2
- SPATA2L | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 25/248 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs771688020, COSV57045883; called by muse, mutect2, varscan2
- SPATS2 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs776164528; called by mutect2, varscan2
- SPDYE5 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 78/377 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.149); catalogued as rs1554483083; called by muse, mutect2, varscan2
- SSB | c.578del p.N193Mfs*13 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | catalogued as rs753297385; called by mutect2, varscan2
- SUCO | c.1676T>C p.V559A | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV55263111; called by muse, mutect2
- SURF6 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1384686033, COSV100921185; called by muse, mutect2, varscan2
- TBX1 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 58/448 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.167); catalogued as COSV60354347, COSV60354601; called by muse, mutect2, varscan2
- TBXT | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 62/467 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV51617239; called by muse, varscan2
- TCEAL6 | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.998); catalogued as rs782217171, COSV65653883; called by muse, mutect2, varscan2
- TENM4 | c.2294C>T p.A765V | Missense Mutation (SNP) | VAF 49/404 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.028); catalogued as rs775572268; called by muse, mutect2, varscan2
- TEPSIN | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 40/300 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs549882677; called by muse, mutect2, varscan2
- THAP12 | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as rs746328804; called by muse, mutect2, varscan2
- TKT | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 43/354 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.042); catalogued as rs782284885; called by muse, mutect2, varscan2
- TNFAIP3 | c.1684C>T p.R562C | Missense Mutation (SNP) | VAF 51/330 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV52800566; called by muse, mutect2, varscan2
- TRABD | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 51/244 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs747329304; called by muse, mutect2, varscan2
- TRMT2A | c.1549+1G>A p.X517_splice | Splice Site (SNP) | VAF 21/193 reads (11%) | catalogued as rs139916507; called by muse, mutect2, varscan2
- TTI1 | c.2120G>A p.R707H | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as rs141770247, COSV65060275; called by muse, mutect2, varscan2
- TTN | c.68876G>A p.G22959D (on ENST00000591111; = p.G15535D on NM_003319.4) | Missense Mutation (SNP) | VAF 28/200 reads (14%) | PolyPhen probably damaging (0.999); catalogued as COSV59975256; called by muse, mutect2, varscan2
- TTN | c.9611G>A p.R3204Q (on ENST00000591111; = p.R3158Q on NM_003319.4) | Missense Mutation (SNP) | VAF 46/372 reads (12%) | PolyPhen possibly damaging (0.67); catalogued as rs775137389; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBA3C | c.526del p.Q176Rfs*14 | Frame Shift Del (DEL) | VAF 34/240 reads (14%) | catalogued as rs1274311012; called by mutect2, pindel, varscan2
- TXNDC17 | c.118A>G p.K40E | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.25); catalogued as rs766098533; called by mutect2, varscan2
- UBE2S | c.583A>G p.M195V | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0.024); catalogued as rs770655715; called by muse, mutect2, varscan2
- UGGT1 | c.3175G>A p.A1059T | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1218499495; called by muse, mutect2, varscan2
- UGT1A9 | c.364dup p.S122Ffs*8 | Frame Shift Ins (INS) | VAF 18/142 reads (13%) | catalogued as rs773627969; called by mutect2, varscan2
- UGT8 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 54/337 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs866951708, COSV60418125; called by muse, mutect2, varscan2
- USP35 | c.1059del p.M354Wfs*119 | Frame Shift Del (DEL) | VAF 36/212 reads (17%) | catalogued as rs761345427; called by mutect2, pindel, varscan2
- UTP25 | c.1357dup p.L453Pfs*18 | Frame Shift Ins (INS) | VAF 31/312 reads (10%) | catalogued as rs769364542; called by mutect2, pindel
- VN1R2 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.517); catalogued as COSV100447949; called by muse, mutect2, varscan2
- VPS13D | c.11740G>A p.A3914T | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.524); catalogued as rs757733968, COSV50698756; called by muse, mutect2, varscan2
- WDSUB1 | c.583+1G>A p.X195_splice | Splice Site (SNP) | VAF 5/37 reads (14%) | catalogued as rs1409672012; called by muse, mutect2, varscan2
- WFIKKN2 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 108/686 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs777854021; called by muse, mutect2, varscan2
- WSCD1 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 11/360 reads (3%) | SIFT tolerated (0.6); PolyPhen benign (0.094); catalogued as rs1351125662; called by muse, mutect2
- XDH | c.1370G>A p.G457D | Missense Mutation (SNP) | VAF 48/384 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101052025; called by muse, mutect2, varscan2
- XIRP1 | c.5344G>A p.V1782I | Missense Mutation (SNP) | VAF 37/244 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs1199477816; called by muse, mutect2, varscan2
- ZBTB20 | c.898C>T p.R300C (on ENST00000474710 / NM_001164342.2; = p.R227C on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/514 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61846144; called by muse, mutect2
- ZFC3H1 | c.5413G>A p.E1805K | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as COSV66431531; called by muse, mutect2, varscan2
- ZFP57 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 42/323 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs763672670, COSV65306583; called by muse, mutect2, varscan2
- ZMYM4 | c.868dup p.T290Nfs*9 | Frame Shift Ins (INS) | VAF 5/39 reads (13%) | catalogued as rs1558099586; called by pindel, varscan2
- ZMYND15 | c.604dup p.L202Pfs*12 | Frame Shift Ins (INS) | VAF 35/129 reads (27%) | catalogued as rs1052556839; called by mutect2, pindel, varscan2
- ZNF229 | c.2200C>T p.H734Y | Missense Mutation (SNP) | VAF 70/511 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1248952952; called by muse, mutect2, varscan2
- ZNF273 | c.517A>G p.T173A | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs1423252650; called by muse, mutect2, varscan2
- ZNF282 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs755219989, COSV50480264; called by muse, mutect2, varscan2
- ZNF292 | c.6145del p.S2049Vfs*11 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | catalogued as rs764995318; called by mutect2, varscan2
- ZNF317 | c.1319A>T p.H440L | Missense Mutation (SNP) | VAF 43/369 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs199778120; called by muse, mutect2, varscan2
- ZNF324 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 39/950 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as rs1245828543; called by muse, mutect2
- ZNF426 | c.1141C>T p.Q381* | Nonsense Mutation (SNP) | VAF 30/244 reads (12%) | catalogued as rs747448662; called by muse, mutect2, varscan2
- ZNF667 | c.796T>C p.S266P | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.148); catalogued as rs777644942; called by muse, mutect2, varscan2
- ZNF777 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); catalogued as rs573297784; called by muse, mutect2
- ZNF90 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.882); catalogued as rs376553078; called by muse, mutect2, varscan2
- ZSCAN1 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.49); catalogued as rs775725866, COSV56602072; called by muse, mutect2, varscan2
- AADAT | c.1067del p.L356Yfs*11 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | called by mutect2, pindel, varscan2
- AASS | c.98T>C p.V33A | Missense Mutation (SNP) | VAF 39/361 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- AATK | c.1672G>A p.A558T (on ENST00000326724 / NM_001080395.3; = p.A455T on NM_004920.2) | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABCA13 | c.11362T>C p.Y3788H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCA4 | c.246del p.Q83Kfs*32 | Frame Shift Del (DEL) | VAF 58/582 reads (10%) | called by mutect2, pindel, varscan2
- ABCB1 | c.733T>G p.L245V | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.062); called by muse, mutect2
- ABCB6 | c.595C>A p.L199M | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- ABCC3 | c.3802A>C p.T1268P | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- AC053503.6 | c.339del p.K114Sfs*52 | Frame Shift Del (DEL) | VAF 13/124 reads (10%) | called by mutect2, pindel, varscan2
- ACAD11 | c.1861T>A p.F621I | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACAT1 | c.1050G>T p.W350C | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACP2 | c.73A>G p.M25V | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACTR3B | c.161dup p.V55Sfs*2 | Frame Shift Ins (INS) | VAF 6/72 reads (8%) | called by mutect2, pindel
- ACTR6 | c.68+7A>G | Splice Region (SNP) | VAF 17/153 reads (11%) | called by muse, mutect2, varscan2
- ADAD2 | c.842A>G p.H281R (on ENST00000315906 / NM_001145400.2; = p.H363R on NM_139174.4) | Missense Mutation (SNP) | VAF 71/431 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS20 | c.1602C>G p.C534W | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRL1 | c.251A>G p.Y84C | Missense Mutation (SNP) | VAF 43/264 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADGRL3 | c.3832C>A p.L1278I | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, varscan2
- AFF2 | c.424G>T p.V142L | Missense Mutation (SNP) | VAF 10/251 reads (4%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.97); called by muse, mutect2
- AGPAT4 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 20/399 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.394); called by muse, mutect2
- AHDC1 | c.1758dup p.R587Tfs*56 | Frame Shift Ins (INS) | VAF 29/241 reads (12%) | called by mutect2, varscan2
- AHNAK | c.2432T>C p.M811T | Missense Mutation (SNP) | VAF 35/326 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- AHR | c.1993C>G p.P665A | Missense Mutation (SNP) | VAF 38/216 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- AKAP1 | c.716T>C p.L239S | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- AKAP6 | c.3671T>C p.I1224T | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.307); called by muse, mutect2
- AL031777.2 | c.120C>A p.Y40* | Nonsense Mutation (SNP) | VAF 18/212 reads (8%) | called by muse, mutect2
- ALK | c.1544A>G p.Q515R | Missense Mutation (SNP) | VAF 52/349 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ALPK3 | c.3349del p.E1117Rfs*17 | Frame Shift Del (DEL) | VAF 9/75 reads (12%) | called by mutect2, pindel, varscan2
- ANKAR | c.3923del p.N1308Ifs*14 | Frame Shift Del (DEL) | VAF 22/179 reads (12%) | called by mutect2, pindel, varscan2
- ANKRD13B | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANO1 | c.1976A>C p.E659A | Missense Mutation (SNP) | VAF 47/299 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ANTXRL | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 52/466 reads (11%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.893); called by muse, varscan2
- APCS | c.462G>T p.Q154H | Missense Mutation (SNP) | VAF 53/415 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARFGEF1 | c.3905G>A p.G1302E | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- ARFGEF1 | c.2409dup p.F804Ifs*17 | Frame Shift Ins (INS) | VAF 16/121 reads (13%) | called by mutect2, pindel, varscan2
- ARHGAP20 | c.174del p.K58Nfs*22 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- ARHGAP36 | c.558T>C p.G186= | Splice Region (SNP) | VAF 7/68 reads (10%) | called by muse, mutect2, varscan2
- ARHGEF10L | c.716A>G p.Y239C | Missense Mutation (SNP) | VAF 6/141 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2
- ARHGEF11 | c.1256A>G p.Y419C | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARID1A | c.4899dup p.M1634Hfs*14 | Frame Shift Ins (INS) | VAF 9/71 reads (13%) | called by mutect2, pindel, varscan2
- ASB10 | c.1348dup p.L450Pfs*14 (on ENST00000420175 / NM_001142459.2; = p.L435Pfs*14 on NM_080871.4) | Frame Shift Ins (INS) | VAF 17/143 reads (12%) | called by mutect2, pindel
- ATN1 | c.2436_2437dup p.E813Afs*28 | Frame Shift Ins (INS) | VAF 18/108 reads (17%) | called by mutect2, varscan2
- ATP2B2 | c.3104T>C p.I1035T (on ENST00000352432; = p.I1001T on NM_001683.5) | Missense Mutation (SNP) | VAF 74/668 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- ATP2C1 | c.75dup p.A26Sfs*3 | Frame Shift Ins (INS) | VAF 22/195 reads (11%) | called by mutect2, varscan2
- ATP2C2 | c.2162A>G p.E721G | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATP6V1C2 | c.614A>T p.D205V | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2
- ATRNL1 | c.3702dup p.V1235Cfs*49 | Frame Shift Ins (INS) | VAF 10/63 reads (16%) | called by mutect2, pindel, varscan2
- BCL6 | c.957dup p.N320Qfs*11 | Frame Shift Ins (INS) | VAF 20/166 reads (12%) | called by mutect2, pindel, varscan2
- BEND2 | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- BNC2 | c.188dup p.R64Efs*13 | Frame Shift Ins (INS) | VAF 30/256 reads (12%) | called by mutect2, pindel, varscan2
- BRAT1 | c.884_888dup p.P297Wfs*9 | Frame Shift Ins (INS) | VAF 7/64 reads (11%) | called by mutect2, pindel, varscan2
- BRSK2 | c.531G>A p.G177= | Splice Region (SNP) | VAF 40/321 reads (12%) | called by muse, mutect2, varscan2
- C12orf42 | c.211T>C p.F71L | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- C19orf47 | c.471del p.R158Gfs*138 | Frame Shift Del (DEL) | VAF 18/148 reads (12%) | called by mutect2, pindel, varscan2
- C1orf159 | c.596del p.P199Rfs*82 (on ENST00000379339 / NM_001330306.2; = p.P163Rfs*96 on NM_017891.5) | Frame Shift Del (DEL) | VAF 10/88 reads (11%) | called by mutect2, pindel, varscan2
- C1orf43 | c.617A>G p.K206R (on ENST00000368521 / NM_001297718.2; = p.K172R on NM_015449.4) | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- C3 | c.845T>C p.I282T | Missense Mutation (SNP) | VAF 54/633 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.017); called by muse, mutect2
- C6 | c.1721G>A p.W574* | Nonsense Mutation (SNP) | VAF 21/202 reads (10%) | called by muse, mutect2, varscan2
- C7orf26 | c.986T>G p.I329S | Missense Mutation (SNP) | VAF 39/285 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CACNA1A | c.2577G>T p.E859D | Missense Mutation (SNP) | VAF 46/332 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by mutect2, varscan2
- CACTIN | c.728A>G p.E243G | Missense Mutation (SNP) | VAF 12/287 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CALB1 | c.217dup p.I73Nfs*29 | Frame Shift Ins (INS) | VAF 5/36 reads (14%) | called by pindel, varscan2
- CAMSAP3 | c.1100A>G p.Q367R | Missense Mutation (SNP) | VAF 48/311 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CASP8 | c.1068dup p.I357Yfs*8 (on ENST00000432109 / NM_033355.3; = p.I374Yfs*8 on NM_001228.4) | Frame Shift Ins (INS) | VAF 44/429 reads (10%) | called by mutect2, pindel, varscan2
- CCDC88B | c.4052G>C p.G1351A | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.383); called by muse, mutect2
- CCNJ | c.165_166del p.C57Pfs*19 | Frame Shift Del (DEL) | VAF 26/226 reads (12%) | called by pindel, varscan2
- CCR2 | c.72dup p.D25* | Frame Shift Ins (INS) | VAF 30/207 reads (14%) | called by mutect2, pindel, varscan2
- CCR7 | c.74A>G p.Q25R | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- CD248 | c.1584C>G p.H528Q | Missense Mutation (SNP) | VAF 44/247 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDC42SE1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 31/226 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- CDK5RAP2 | c.5437dup p.L1813Pfs*4 | Frame Shift Ins (INS) | VAF 62/429 reads (14%) | called by mutect2, pindel, varscan2
- CDK8 | c.1234A>G p.T412A | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- CELF4 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.98); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CEP170 | c.412A>G p.S138G | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHDH | c.1706A>G p.D569G | Missense Mutation (SNP) | VAF 12/390 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CHRNA7 | c.608G>A p.G203D | Missense Mutation (SNP) | VAF 34/389 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CLMN | c.2320G>T p.A774S | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.194); called by muse, mutect2
- COA3 | c.317C>G p.S106C | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- COBL | c.3651_3654del p.S1218Hfs*23 | Frame Shift Del (DEL) | VAF 42/252 reads (17%) | called by mutect2, pindel, varscan2
- COL4A1 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 57/342 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- COL4A5 | c.3217A>G p.I1073V | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- COL7A1 | c.3831+2T>C p.X1277_splice | Splice Site (SNP) | VAF 107/692 reads (15%) | called by muse, mutect2, varscan2
- COPB1 | c.1366C>T p.R456* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2, varscan2
- CPEB2 | c.2941del p.C981Vfs*31 | Frame Shift Del (DEL) | VAF 20/150 reads (13%) | called by mutect2, pindel, varscan2
- CRP | c.462dup p.Q155Afs*11 | Frame Shift Ins (INS) | VAF 40/312 reads (13%) | called by mutect2, pindel, varscan2
- CYFIP1 | c.428T>C p.L143P | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYP2C19 | c.1118A>G p.D373G | Missense Mutation (SNP) | VAF 42/328 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- CYP2E1 | c.713del p.N238Mfs*5 | Frame Shift Del (DEL) | VAF 9/53 reads (17%) | called by mutect2, pindel, varscan2
- DAPK1 | c.919-2A>G p.X307_splice | Splice Site (SNP) | VAF 8/42 reads (19%) | called by muse, varscan2
- DCAF4L1 | c.460dup p.S154Kfs*19 | Frame Shift Ins (INS) | VAF 40/386 reads (10%) | called by mutect2, varscan2
- DHX32 | c.2180A>G p.Q727R | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DIO1 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 14/292 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.009); called by muse, mutect2
- DLGAP3 | c.1130del p.G377Vfs*91 | Frame Shift Del (DEL) | VAF 66/478 reads (14%) | called by mutect2, varscan2
- DMP1 | c.-20T>C | Splice Region (SNP) | VAF 25/199 reads (13%) | called by muse, mutect2, varscan2
- DNAH11 | c.12268T>C p.C4090R | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNHD1 | c.3103T>A p.W1035R | Missense Mutation (SNP) | VAF 27/302 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DOCK2 | c.1118A>G p.D373G | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- DUSP7 | c.626dup p.L210Pfs*6 | Frame Shift Ins (INS) | VAF 44/317 reads (14%) | called by mutect2, pindel, varscan2
- EFCC1 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 13/191 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); called by muse, mutect2
- EGFL6 | c.271T>C p.C91R | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2
- EIF4B | c.988del p.Q330Kfs*5 | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | called by mutect2, pindel, varscan2
- ELN | c.1052T>A p.I351N | Missense Mutation (SNP) | VAF 146/655 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.663); called by muse, varscan2
- ELP3 | c.19+8A>G | Splice Region (SNP) | VAF 19/87 reads (22%) | called by muse, mutect2, varscan2
- EML1 | c.2231C>T p.A744V | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- EPB41L1 | c.1449+2T>C p.X483_splice | Splice Site (SNP) | VAF 40/711 reads (6%) | called by muse, mutect2
- EPB42 | c.1618+7C>T | Splice Region (SNP) | VAF 10/82 reads (12%) | called by muse, mutect2
- ERVV-2 | c.485T>C p.L162S | Missense Mutation (SNP) | VAF 26/272 reads (10%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- FAM186B | c.248T>A p.I83N | Missense Mutation (SNP) | VAF 82/377 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- FAM20C | c.1333A>G p.M445V | Missense Mutation (SNP) | VAF 36/300 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- FBXO30 | c.248G>A p.C83Y | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBXW4 | c.1361T>C p.V454A | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- FGF5 | c.613dup p.R205Pfs*3 | Frame Shift Ins (INS) | VAF 16/145 reads (11%) | called by mutect2, pindel, varscan2
- FHOD3 | c.2740T>C p.C914R (on ENST00000359247 / NM_001281739.3; = p.C931R on NM_025135.5) | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- FLG2 | c.582A>C p.K194N | Missense Mutation (SNP) | VAF 43/278 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- FLNC | c.6841dup p.Q2281Pfs*31 | Frame Shift Ins (INS) | VAF 91/873 reads (10%) | called by mutect2, pindel, varscan2
- FLT4 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 116/815 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FOLR1 | c.497T>C p.F166S | Missense Mutation (SNP) | VAF 95/595 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FOXO4 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FOXP1 | c.447dup p.Q150Tfs*20 | Frame Shift Ins (INS) | VAF 28/266 reads (11%) | called by mutect2, pindel
- FREM1 | c.6493T>C p.C2165R | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FRMD4A | c.173A>G p.K58R | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FSTL5 | c.2373G>A p.W791* | Nonsense Mutation (SNP) | VAF 31/265 reads (12%) | called by muse, mutect2, varscan2
- GALE | c.607G>A p.G203S | Missense Mutation (SNP) | VAF 98/686 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- GALNT1 | c.824T>C p.M275T | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- GPAT2 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 39/326 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPR161 | c.1504C>A p.R502S | Missense Mutation (SNP) | VAF 28/323 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); called by muse, mutect2
- GPR20 | c.646A>G p.T216A | Missense Mutation (SNP) | VAF 49/358 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by mutect2, varscan2
- GRM1 | c.466A>C p.I156L | Missense Mutation (SNP) | VAF 24/562 reads (4%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.799); called by muse, mutect2
- GTF2F1 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 62/491 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- H2AC4 | c.86G>A p.G29D | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HEATR1 | c.703T>A p.S235T | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HELZ2 | c.4988T>C p.L1663P (on ENST00000467148 / NM_001037335.2; = p.L1094P on NM_033405.3) | Missense Mutation (SNP) | VAF 65/446 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HIC1 | c.1748G>A p.R583H (on ENST00000322941 / NM_001098202.1; = p.R564H on NM_006497.4) | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- HIRIP3 | c.1307del p.C436Lfs*21 | Frame Shift Del (DEL) | VAF 32/198 reads (16%) | called by mutect2, pindel, varscan2
- HLA-C | c.790A>G p.T264A | Missense Mutation (SNP) | VAF 24/496 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- HMGB3 | c.597_599dup p.D199dup | In Frame Ins (INS) | VAF 4/42 reads (10%) | called by mutect2, pindel
- HNRNPA3 | c.554-3del | Splice Region (DEL) | VAF 10/86 reads (12%) | called by mutect2, pindel, varscan2
- HOXD9 | c.226T>G p.S76A | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- IFT122 | c.3248T>C p.F1083S (on ENST00000348417 / NM_052989.3; = p.F1024S on NM_018262.4) | Missense Mutation (SNP) | VAF 14/417 reads (3%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.543); called by muse, mutect2
- IGLV1-51 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 17/160 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- IL17D | c.373G>A p.G125S | Missense Mutation (SNP) | VAF 12/289 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- IL20RA | c.404-2A>C p.X135_splice | Splice Site (SNP) | VAF 20/126 reads (16%) | called by muse, mutect2, varscan2
- IL2RA | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 17/179 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- IRF2BPL | c.182A>G p.H61R | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- ISYNA1 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 80/647 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITGA6 | c.1265del p.N422Ifs*35 (on ENST00000442250; = p.N383Ifs*35 on NM_000210.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 30/312 reads (10%) | called by mutect2, pindel, varscan2
- ITGA7 | c.749del p.G250Efs*23 (on ENST00000555728; = p.G250Efs*34 on NM_001144996.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 10/103 reads (10%) | called by mutect2, pindel, varscan2
- JADE1 | c.2121dup p.Q708Afs*24 | Frame Shift Ins (INS) | VAF 29/192 reads (15%) | called by mutect2, pindel, varscan2
- KATNIP | c.4325C>T p.P1442L | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNA3 | c.1630del p.Q544Rfs*35 | Frame Shift Del (DEL) | VAF 32/330 reads (10%) | called by mutect2, pindel
- KCTD19 | c.1475A>G p.K492R | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- KDM6A | c.2595dup p.M866Hfs*9 | Frame Shift Ins (INS) | VAF 20/165 reads (12%) | called by mutect2, pindel, varscan2
- KHDC1 | c.589C>T p.P197S (on ENST00000370384 / NM_001251874.2; = p.P124S on NM_030568.5) | Missense Mutation (SNP) | VAF 40/377 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- KIAA0100 | c.4814T>G p.L1605R | Missense Mutation (SNP) | VAF 41/324 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIAA1109 | c.7351A>G p.I2451V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- KIF1A | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- KIF21A | c.387del p.K129Nfs*3 | Frame Shift Del (DEL) | VAF 22/96 reads (23%) | called by mutect2, varscan2
- KLC3 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 69/417 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- KLF4 | c.1264+2T>C p.X422_splice | Splice Site (SNP) | VAF 16/146 reads (11%) | called by muse, mutect2, varscan2
- KRT7 | c.188T>C p.I63T | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- KRT78 | c.1279dup p.E427Gfs*33 | Frame Shift Ins (INS) | VAF 25/192 reads (13%) | called by mutect2, pindel, varscan2
- KRTAP12-4 | c.120dup p.C41Lfs*62 | Frame Shift Ins (INS) | VAF 50/472 reads (11%) | called by mutect2, pindel, varscan2
- LAMP2 | c.701T>C p.L234P | Missense Mutation (SNP) | VAF 15/252 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LBHD1 | c.313dup p.H105Pfs*2 (on ENST00000431002 / NM_001367940.1; = p.H79Pfs*2 on NM_024099.3) | Frame Shift Ins (INS) | VAF 12/120 reads (10%) | called by mutect2, varscan2
- LGR6 | c.2777G>A p.G926E (on ENST00000367278 / NM_001017403.1; = p.G874E on NM_021636.3) | Missense Mutation (SNP) | VAF 40/287 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- LHX1 | c.10T>C p.C4R | Missense Mutation (SNP) | VAF 32/277 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LILRB5 | c.1529T>C p.L510P (on ENST00000449561 / NM_001081442.3; = p.L509P on NM_006840.5) | Missense Mutation (SNP) | VAF 11/326 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.049); called by muse, mutect2
- LINC02272 | n.232T>C | Splice Region (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- LOXHD1 | c.2189A>G p.Y730C | Missense Mutation (SNP) | VAF 31/239 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LRIT1 | c.393dup p.K132Qfs*18 | Frame Shift Ins (INS) | VAF 28/282 reads (10%) | called by mutect2, pindel
- LRRC73 | c.307G>T p.A103S | Missense Mutation (SNP) | VAF 29/227 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LRRTM3 | c.212A>T p.N71I | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LYPD4 | c.24dup p.V9Cfs*23 | Frame Shift Ins (INS) | VAF 16/117 reads (14%) | called by mutect2, pindel, varscan2
- MAEA | c.374T>C p.M125T | Missense Mutation (SNP) | VAF 69/534 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP2K3 | c.476T>C p.M159T (on ENST00000342679 / NM_145109.3; = p.M130T on NM_002756.4) | Missense Mutation (SNP) | VAF 19/406 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.069); called by muse, mutect2
- MAP4K2 | c.614T>C p.I205T | Missense Mutation (SNP) | VAF 29/621 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MARK2 | c.1687dup p.Q563Pfs*24 (on ENST00000402010 / NM_001039469.2; = p.Q508Pfs*24 on NM_004954.5) | Frame Shift Ins (INS) | VAF 32/354 reads (9%) | called by mutect2, pindel, varscan2
- MAST3 | c.1915T>C p.F639L | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); called by muse, varscan2
- MEX3D | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 20/465 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MGAT3 | c.1039T>C p.S347P | Missense Mutation (SNP) | VAF 60/393 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MICOS10 | c.151T>A p.L51I | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- MINDY4 | c.2183A>G p.D728G | Missense Mutation (SNP) | VAF 23/231 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MKI67 | c.6983C>G p.T2328S | Missense Mutation (SNP) | VAF 47/264 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MMP28 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 54/268 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- MPPE1 | c.844C>T p.L282F | Missense Mutation (SNP) | VAF 42/316 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MRAS | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 23/229 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MSH3 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTG1 | c.573+2T>C p.X191_splice | Splice Site (SNP) | VAF 13/89 reads (15%) | called by muse, mutect2, varscan2
- MUC20 | c.1539del p.A515Pfs*40 | Frame Shift Del (DEL) | VAF 47/425 reads (11%) | called by mutect2, pindel, varscan2
- MUC5B | c.16274G>A p.G5425E | Missense Mutation (SNP) | VAF 37/256 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MYH1 | c.4946A>T p.N1649I | Missense Mutation (SNP) | VAF 82/352 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- MYH10 | c.1604del p.L535Wfs*35 | Frame Shift Del (DEL) | VAF 13/50 reads (26%) | called by mutect2, pindel, varscan2
- MYH13 | c.4292A>T p.D1431V | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYO18B | c.1841G>C p.R614P | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- MYO18B | c.2764G>A p.A922T | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.503); called by muse, mutect2
- MYO19 | c.1469A>G p.E490G | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYO19 | c.983A>G p.K328R | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.028); called by muse, mutect2
- MYO7B | c.3671T>C p.M1224T | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYORG | c.1906C>G p.P636A | Missense Mutation (SNP) | VAF 22/603 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NCOR1 | c.4387C>G p.L1463V | Missense Mutation (SNP) | VAF 37/246 reads (15%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- NCOR2 | c.2538dup p.A847Rfs*3 | Frame Shift Ins (INS) | VAF 22/91 reads (24%) | called by mutect2, pindel, varscan2
- NDFIP2 | c.684dup p.N229Efs*2 | Frame Shift Ins (INS) | VAF 14/108 reads (13%) | called by mutect2, pindel, varscan2
- NEK11 | c.1598dup p.N533Kfs*18 | Frame Shift Ins (INS) | VAF 7/56 reads (13%) | called by mutect2, pindel, varscan2
- NES | c.4085A>C p.D1362A | Missense Mutation (SNP) | VAF 36/238 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.147); called by muse, varscan2
- NES | c.4057dup p.E1353Gfs*10 | Frame Shift Ins (INS) | VAF 28/218 reads (13%) | called by pindel, varscan2
- NIBAN1 | c.269A>G p.Y90C | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOL8 | c.88A>G p.R30G | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2
- NOVA1 | c.571G>T p.G191C | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- NOXRED1 | c.479T>C p.L160P | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, varscan2
- NPAS2 | c.1330A>G p.R444G | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- NPSR1 | c.830T>C p.I277T | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.243); called by muse, mutect2
- NR1H4 | c.587A>G p.K196R (on ENST00000551379 / NM_001206993.2; = p.K186R on NM_005123.4) | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRK | c.1875G>A p.W625* | Nonsense Mutation (SNP) | VAF 10/170 reads (6%) | called by muse, mutect2
- NUP160 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2
- NUP88 | c.1652A>G p.E551G | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- NXF3 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- OR2B2 | c.870_871del p.L292* | Frame Shift Del (DEL) | VAF 14/112 reads (13%) | called by pindel, varscan2
- OR2M4 | c.164T>A p.L55H | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2Z1 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 10/187 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2
- OR5B21 | c.125dup p.M43Nfs*21 | Frame Shift Ins (INS) | VAF 32/327 reads (10%) | called by mutect2, pindel, varscan2
- OR6N2 | c.509C>A p.A170D | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- ORC2 | c.1253T>G p.I418S | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- OXR1 | c.1966T>C p.S656P | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PAPPA | c.3502T>C p.S1168P | Missense Mutation (SNP) | VAF 65/569 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PASD1 | c.1508T>C p.L503P | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- PCDHA2 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 154/1144 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDE3A | c.629T>C p.L210P | Missense Mutation (SNP) | VAF 94/464 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.368); called by muse, varscan2
- PENK | c.64G>T p.V22L | Missense Mutation (SNP) | VAF 56/446 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.296); called by muse, varscan2
- PEX6 | c.36dup p.P13Sfs*65 | Frame Shift Ins (INS) | VAF 15/136 reads (11%) | called by mutect2, pindel, varscan2
- PFKFB4 | c.101G>A p.C34Y | Missense Mutation (SNP) | VAF 34/206 reads (17%) | PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PGGHG | c.2149dup p.L717Pfs*21 | Frame Shift Ins (INS) | VAF 39/205 reads (19%) | called by mutect2, pindel, varscan2
- PGLYRP2 | c.1162T>C p.W388R | Missense Mutation (SNP) | VAF 14/281 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PHF7 | c.469dup p.E157Gfs*9 | Frame Shift Ins (INS) | VAF 14/106 reads (13%) | called by mutect2, pindel, varscan2
- PIDD1 | c.883del p.L295Wfs*25 | Frame Shift Del (DEL) | VAF 41/312 reads (13%) | called by mutect2, pindel, varscan2
- PIK3R6 | c.665T>C p.L222P | Missense Mutation (SNP) | VAF 15/220 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.399); called by muse, mutect2
- PIWIL4 | c.2168+2T>C p.X723_splice | Splice Site (SNP) | VAF 8/122 reads (7%) | called by muse, mutect2
- PLCXD1 | c.373T>C p.Y125H | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PLEC | c.7409A>T p.Q2470L (on ENST00000322810 / NM_201380.4; = p.Q2360L on NM_000445.5) | Missense Mutation (SNP) | VAF 158/677 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- PLK2 | c.1128dup p.D377Rfs*7 | Frame Shift Ins (INS) | VAF 4/33 reads (12%) | called by pindel, varscan2
- POTEF | c.2182dup p.R728Pfs*54 | Frame Shift Ins (INS) | VAF 67/594 reads (11%) | called by mutect2, varscan2
- POU4F2 | c.736G>T p.G246C | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- PPM1L | c.983C>A p.A328D | Missense Mutation (SNP) | VAF 22/366 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PPP1R13L | c.65T>C p.M22T | Missense Mutation (SNP) | VAF 43/238 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PPWD1 | c.355del p.I119* | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | called by mutect2, pindel, varscan2
- PRDM16 | c.2718_2719del p.K907Afs*75 | Frame Shift Del (DEL) | VAF 22/194 reads (11%) | called by pindel, varscan2
- PRKD2 | c.578A>C p.K193T | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PROM1 | c.122_123del p.Y41* | Frame Shift Del (DEL) | VAF 15/113 reads (13%) | called by mutect2, pindel, varscan2
- PRPF4B | c.2263A>G p.R755G | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PRPF6 | c.152dup p.G52Rfs*16 | Frame Shift Ins (INS) | VAF 67/414 reads (16%) | called by mutect2, pindel, varscan2
- PRR12 | c.1358A>G p.Q453R (on ENST00000615927; = p.Q1274R on NM_020719.3) | Missense Mutation (SNP) | VAF 19/289 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by muse, mutect2
- PRR22 | c.1085A>G p.D362G | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- PRRC2B | c.3914del p.P1305Hfs*161 | Frame Shift Del (DEL) | VAF 17/109 reads (16%) | called by mutect2, pindel, varscan2
- PSG8 | c.1272A>G p.I424M | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- PSMC1 | c.346A>G p.I116V | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PSMD1 | c.71T>C p.L24P | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- PSMF1 | c.479del p.P160Lfs*39 | Frame Shift Del (DEL) | VAF 31/192 reads (16%) | called by mutect2, pindel, varscan2
- PTPDC1 | c.1636dup p.R546Pfs*17 (on ENST00000375360 / NM_177995.3; = p.R598Pfs*17 on NM_152422.4) | Frame Shift Ins (INS) | VAF 34/238 reads (14%) | called by mutect2, pindel, varscan2
- PTPRO | c.3361G>A p.V1121I (on ENST00000281171 / NM_030667.3; = p.V1093I on NM_002848.4) | Missense Mutation (SNP) | VAF 18/392 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); called by muse, mutect2
- RAD51AP2 | c.858del p.E287Rfs*31 | Frame Shift Del (DEL) | VAF 17/107 reads (16%) | called by mutect2, pindel, varscan2
- RAPGEF3 | c.2237dup p.E747Gfs*81 (on ENST00000389212; = p.E705Gfs*81 on NM_006105.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 44/446 reads (10%) | called by mutect2, pindel
- RBFOX3 | c.21del p.A8Pfs*38 | Frame Shift Del (DEL) | VAF 10/74 reads (14%) | called by mutect2, pindel
- RBM5 | c.1569dup p.E524Rfs*26 | Frame Shift Ins (INS) | VAF 8/40 reads (20%) | called by mutect2, pindel, varscan2
- REV3L | c.4070dup p.N1357Kfs*4 | Frame Shift Ins (INS) | VAF 12/95 reads (13%) | called by mutect2, varscan2
- RGL1 | c.548A>C p.D183A (on ENST00000360851 / NM_001297672.2; = p.D218A on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- RGL1 | c.890dup p.K298Qfs*13 (on ENST00000360851 / NM_001297672.2; = p.K333Qfs*13 on NM_015149.5 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 23/170 reads (14%) | called by mutect2, pindel, varscan2
- RMC1 | c.1697T>A p.V566E | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- RNF19A | c.1508T>C p.I503T | Missense Mutation (SNP) | VAF 44/301 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- RNF19A | c.187del p.R63Efs*5 | Frame Shift Del (DEL) | VAF 25/192 reads (13%) | called by mutect2, pindel, varscan2
- RNF213 | c.8873G>A p.S2958N | Missense Mutation (SNP) | VAF 64/530 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- RNF34 | c.541del p.S181Qfs*71 | Frame Shift Del (DEL) | VAF 46/164 reads (28%) | called by mutect2, pindel, varscan2
- RSPH6A | c.2015G>A p.G672D | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2
- SAMD5 | c.100A>G p.K34E | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SBDS | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 33/275 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- SBF2 | c.2744_2746del p.E915del | In Frame Del (DEL) | VAF 26/292 reads (9%) | called by mutect2, pindel
- SCAMP2 | c.679dup p.C227Lfs*30 | Frame Shift Ins (INS) | VAF 17/83 reads (20%) | called by mutect2, varscan2
- SCARB1 | c.346T>C p.Y116H | Missense Mutation (SNP) | VAF 91/711 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- SCLT1 | c.1269del p.A424Qfs*6 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | called by mutect2, varscan2
- SCN2A | c.3937C>T p.P1313S | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCNN1D | c.1707G>A p.W569* (on ENST00000338555; = p.W733* on NM_001130413.4) | Nonsense Mutation (SNP) | VAF 31/298 reads (10%) | called by muse, mutect2, varscan2
- SDR39U1 | c.795del p.K266Rfs*2 | Frame Shift Del (DEL) | VAF 43/269 reads (16%) | called by mutect2, pindel, varscan2
- SDS | c.559del p.D187Tfs*39 | Frame Shift Del (DEL) | VAF 80/351 reads (23%) | called by mutect2, pindel, varscan2
- SEMA6A | c.2096T>C p.M699T | Missense Mutation (SNP) | VAF 26/318 reads (8%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.991); called by muse, mutect2
- SEMA6D | c.680T>C p.I227T | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SLC12A8 | c.763_764dup p.D256Afs*46 | Frame Shift Ins (INS) | VAF 23/207 reads (11%) | called by pindel, varscan2
- SLC13A1 | c.1240+2T>C p.X414_splice | Splice Site (SNP) | VAF 12/60 reads (20%) | called by muse, mutect2, varscan2
- SLC52A1 | c.176A>G p.N59S | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLC7A6 | c.247G>T p.V83L | Missense Mutation (SNP) | VAF 26/512 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.019); called by muse, mutect2
- SMOC1 | c.880A>C p.S294R | Missense Mutation (SNP) | VAF 47/311 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- SNX6 | c.1096dup p.I366Nfs*3 (on ENST00000652385; = p.I238Nfs*3 on NM_021249.5) | Frame Shift Ins (INS) | VAF 12/80 reads (15%) | called by mutect2, pindel, varscan2
- SORBS1 | c.3403del p.A1135Qfs*17 | Frame Shift Del (DEL) | VAF 26/228 reads (11%) | called by mutect2, pindel, varscan2
- SOWAHB | c.1685del p.G562Vfs*32 | Frame Shift Del (DEL) | VAF 21/99 reads (21%) | called by mutect2, pindel, varscan2
- SOWAHD | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SPNS2 | c.427C>A p.L143M | Missense Mutation (SNP) | VAF 10/227 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- SRMS | c.93del p.S33Pfs*38 | Frame Shift Del (DEL) | VAF 26/119 reads (22%) | called by mutect2, pindel, varscan2
- SSRP1 | c.1132A>G p.N378D | Missense Mutation (SNP) | VAF 48/345 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- STK39 | c.1625T>C p.L542S | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SUN1 | c.1057dup p.S353Ffs*13 (on ENST00000405266 / NM_001367651.1; = p.S233Ffs*13 on NM_025154.6 and 13 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 22/127 reads (17%) | called by mutect2, pindel, varscan2
- SUPT6H | c.1199A>G p.D400G | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNE1 | c.9656T>C p.V3219A (on ENST00000367255 / NM_182961.4; = p.V3226A on NM_033071.3) | Missense Mutation (SNP) | VAF 20/530 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2
- SYNE2 | c.4991del p.K1664Rfs*11 | Frame Shift Del (DEL) | VAF 14/85 reads (16%) | called by mutect2, pindel, varscan2
- SYNPO | c.2027A>G p.Q676R (on ENST00000394243 / NM_001166208.2; = p.Q432R on NM_007286.6) | Missense Mutation (SNP) | VAF 43/245 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- SZT2 | c.7361G>T p.G2454V (on ENST00000634258 / NM_001365999.1; = p.G2397V on NM_015284.4) | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TAMM41 | c.1275del p.S426Pfs*6 | Frame Shift Del (DEL) | VAF 13/90 reads (14%) | called by mutect2, pindel, varscan2
- TCF7L1 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TECR | c.671A>T p.K224M | Missense Mutation (SNP) | VAF 106/660 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TEX13C | c.719T>C p.M240T | Missense Mutation (SNP) | VAF 34/425 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.38); called by muse, mutect2
- TEX45 | c.590C>T p.T197I | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.012); called by muse, mutect2
- THBD | c.364T>C p.W122R | Missense Mutation (SNP) | VAF 30/274 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- THBS1 | c.3192A>C p.K1064N | Missense Mutation (SNP) | VAF 39/337 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TJP1 | c.2384dup p.N795Kfs*17 | Frame Shift Ins (INS) | VAF 7/49 reads (14%) | called by mutect2, pindel, varscan2
- TLCD2 | c.635T>C p.I212T | Missense Mutation (SNP) | VAF 31/618 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- TMC6 | c.101T>C p.F34S | Missense Mutation (SNP) | VAF 118/793 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- TMEM182 | c.449del p.G150Efs*15 | Frame Shift Del (DEL) | VAF 18/150 reads (12%) | called by mutect2, pindel, varscan2
- TMPRSS12 | c.537del p.A180Qfs*2 | Frame Shift Del (DEL) | VAF 35/145 reads (24%) | called by mutect2, pindel, varscan2
- TNFRSF10B | c.215dup p.R73Efs*20 | Frame Shift Ins (INS) | VAF 23/240 reads (10%) | called by mutect2, pindel, varscan2
- TNRC6B | c.2251del p.E751Rfs*41 | Frame Shift Del (DEL) | VAF 17/148 reads (11%) | called by mutect2, pindel, varscan2
- TOB2 | c.584del p.G195Afs*9 | Frame Shift Del (DEL) | VAF 66/520 reads (13%) | called by mutect2, pindel, varscan2
- TRAPPC3L | c.307T>G p.F103V | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TREML2 | c.772A>G p.M258V | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIL | c.1427T>C p.V476A | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, varscan2
- TRIM24 | c.2321A>G p.E774G (on ENST00000343526 / NM_015905.3; = p.E740G on NM_003852.4) | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TRIML2 | c.4T>C p.S2P | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.229); called by muse, mutect2
- TRPS1 | c.2318A>T p.K773M (on ENST00000220888 / NM_001330599.2; = p.K786M on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/600 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TSPAN2 | c.98G>T p.G33V | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TTN | c.48263T>C p.L16088P (on ENST00000591111; = p.L8664P on NM_003319.4) | Missense Mutation (SNP) | VAF 23/173 reads (13%) | PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- TTN | c.20332del p.S6778Qfs*9 (on ENST00000591111; = p.S5851Qfs*9 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 29/264 reads (11%) | called by mutect2, pindel, varscan2
- TTN | c.16202G>T p.S5401I (on ENST00000591111; = p.S4474I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/101 reads (13%) | PolyPhen benign (0.037); called by muse, mutect2, varscan2
- UBE2N | c.16dup p.R6Pfs*24 | Frame Shift Ins (INS) | VAF 13/99 reads (13%) | called by mutect2, pindel, varscan2
- UBL7 | c.685C>T p.L229F | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- UBTF | c.475-3del | Splice Region (DEL) | VAF 33/226 reads (15%) | called by mutect2, pindel, varscan2
- UGGT1 | c.1575A>G p.I525M | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- UGT2B11 | c.1191dup p.D398* | Frame Shift Ins (INS) | VAF 28/238 reads (12%) | called by mutect2, varscan2
- UGT3A2 | c.530T>C p.L177P | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); called by muse, mutect2
- UMOD | c.503T>A p.L168H | Missense Mutation (SNP) | VAF 87/655 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- USO1 | c.29del p.G10Vfs*21 | Frame Shift Del (DEL) | VAF 9/98 reads (9%) | called by mutect2, pindel
- USP47 | c.2702A>C p.E901A (on ENST00000399455 / NM_001372095.1; = p.E813A on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/241 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- USP54 | c.2531G>A p.R844K | Missense Mutation (SNP) | VAF 43/334 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- VANGL2 | c.799A>G p.S267G | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- VIPAS39 | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- WDFY3 | c.7304A>G p.Y2435C | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- WDR62 | c.3303C>A p.S1101R | Missense Mutation (SNP) | VAF 86/590 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- XPC | c.1765T>C p.W589R | Missense Mutation (SNP) | VAF 53/476 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZBTB14 | c.1254dup p.T419Yfs*31 | Frame Shift Ins (INS) | VAF 29/276 reads (11%) | called by mutect2, pindel, varscan2
- ZC3H18 | c.512T>C p.V171A | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFHX3 | c.8650T>G p.S2884A | Missense Mutation (SNP) | VAF 52/426 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ZFYVE16 | c.1423T>C p.S475P | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF106 | c.4512dup p.G1505Rfs*15 | Frame Shift Ins (INS) | VAF 5/40 reads (13%) | called by mutect2, pindel, varscan2
- ZNF197 | c.736A>G p.M246V | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.554); called by muse, mutect2
- ZNF207 | c.1001G>A p.S334N | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- ZNF236 | c.2939G>A p.S980N | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- ZNF292 | c.3470del p.L1157Cfs*5 | Frame Shift Del (DEL) | VAF 32/208 reads (15%) | called by mutect2, varscan2
- ZNF503 | c.1694C>T p.A565V | Missense Mutation (SNP) | VAF 11/247 reads (4%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); called by muse, mutect2
- ZNF551 | c.751T>C p.Y251H | Missense Mutation (SNP) | VAF 44/263 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ZNF578 | c.638dup p.H214Pfs*21 | Frame Shift Ins (INS) | VAF 17/144 reads (12%) | called by mutect2, pindel, varscan2
- ZNF607 | c.1276T>C p.C426R | Missense Mutation (SNP) | VAF 21/197 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF729 | c.233A>C p.E78A | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- ZNFX1 | c.5750T>C p.M1917T | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.049); called by muse, mutect2
- ZNFX1 | c.4985A>G p.E1662G | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ABHD16B | c.729C>A p.V243= | Silent (SNP) | VAF 29/522 reads (6%) | called by muse, mutect2
- ADAM19 | c.2412T>C p.P804= | Silent (SNP) | VAF 29/171 reads (17%) | catalogued as rs767512014; called by muse, mutect2, varscan2
- ADGRE3 | c.1419C>T p.G473= | Silent (SNP) | VAF 22/195 reads (11%) | catalogued as rs778319481, COSV53729996; called by muse, mutect2, varscan2
- AFMID | c.171G>A p.R57= | Silent (SNP) | VAF 18/102 reads (18%) | called by muse, mutect2, varscan2
- AFMID | c.552G>A p.T184= | Silent (SNP) | VAF 28/207 reads (14%) | catalogued as rs369871938; called by muse, mutect2, varscan2
- AKAP8L | c.40T>C p.L14= | Silent (SNP) | VAF 21/104 reads (20%) | called by muse, mutect2, varscan2
- AMIGO3 | c.774G>A p.A258= | Silent (SNP) | VAF 42/287 reads (15%) | called by muse, mutect2, varscan2
- ANKRD11 | c.5370G>A p.S1790= | Silent (SNP) | VAF 37/199 reads (19%) | catalogued as rs776244135, COSV99969277, COSV99970226; called by muse, mutect2, varscan2
- APOBEC3F | c.978C>A p.A326= | Silent (SNP) | VAF 53/354 reads (15%) | called by muse, mutect2, varscan2
- APOL2 | c.991C>T p.L331= | Silent (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- ARFGEF1 | c.5190G>A p.G1730= | Silent (SNP) | VAF 7/97 reads (7%) | called by muse, mutect2
- ARRDC2 | c.775C>A p.R259= | Silent (SNP) | VAF 66/247 reads (27%) | catalogued as COSV55846165; called by muse, mutect2, varscan2
- ARRDC5 | c.879C>T p.Y293= (on ENST00000381781; = p.Y279= on NM_001080523.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/335 reads (13%) | catalogued as rs764738190, COSV101108052; called by mutect2, varscan2
- ATP2A2 | c.366T>C p.Y122= | Silent (SNP) | VAF 19/166 reads (11%) | catalogued as CM990229; called by muse, mutect2, varscan2
- ATP2B2 | c.1308C>T p.G436= (on ENST00000352432; = p.G402= on NM_001683.5) | Silent (SNP) | VAF 71/507 reads (14%) | catalogued as rs754134832, COSV59491045; called by muse, mutect2, varscan2
- ATP4A | c.921G>A p.A307= | Silent (SNP) | VAF 61/460 reads (13%) | catalogued as rs371925816, COSV52866875, COSV99382821; called by muse, mutect2, varscan2
- B3GNTL1 | c.30C>A p.S10= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as rs1363996800; called by muse, varscan2
- B4GALT1 | c.255G>T p.P85= | Silent (SNP) | VAF 28/191 reads (15%) | catalogued as COSV65708537; called by muse, mutect2, varscan2
- BBOF1 | c.1137G>A p.K379= | Silent (SNP) | VAF 21/166 reads (13%) | called by muse, mutect2, varscan2
- BCL2L14 | c.912C>T p.N304= | Silent (SNP) | VAF 46/222 reads (21%) | called by muse, mutect2, varscan2
- BCL9L | c.924G>A p.P308= | Silent (SNP) | VAF 29/152 reads (19%) | catalogued as rs369121193; called by muse, mutect2, varscan2
- BCORL1 | c.1764G>A p.E588= | Silent (SNP) | VAF 23/318 reads (7%) | called by muse, mutect2
- BICRA | c.681G>A p.A227= | Silent (SNP) | VAF 27/169 reads (16%) | catalogued as rs1445548493; called by muse, mutect2, varscan2
- BRICD5 | c.672C>T p.H224= | Silent (SNP) | VAF 82/563 reads (15%) | catalogued as rs773032940, COSV57032026; called by muse, mutect2, varscan2
- CCM2 | c.597T>C p.A199= | Silent (SNP) | VAF 92/896 reads (10%) | called by muse, mutect2
- CCN2 | c.858A>G p.V286= | Silent (SNP) | VAF 33/291 reads (11%) | catalogued as COSV63466693; called by muse, mutect2, varscan2
- CCNA1 | c.793C>T p.L265= | Silent (SNP) | VAF 23/141 reads (16%) | catalogued as COSV55221784; called by muse, mutect2, varscan2
- CHST1 | c.390C>T p.C130= | Silent (SNP) | VAF 32/297 reads (11%) | catalogued as COSV57323915; called by muse, mutect2, varscan2
- CLEC4M | c.147C>T p.G49= | Silent (SNP) | VAF 25/149 reads (17%) | catalogued as rs539558959, COSV50217604; called by muse, mutect2, varscan2
- CMYA5 | c.9954G>A p.A3318= | Silent (SNP) | VAF 16/151 reads (11%) | catalogued as rs746975336, COSV71406465; called by muse, mutect2, varscan2
- CNBD2 | c.1357A>C p.R453= (on ENST00000373973 / NM_001365709.1; = p.R449= on NM_080834.4) | Silent (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2, varscan2
- CNTNAP1 | c.867T>C p.N289= | Silent (SNP) | VAF 10/172 reads (6%) | catalogued as rs1229628599; called by muse, mutect2
- COL28A1 | c.408C>T p.A136= | Silent (SNP) | VAF 21/135 reads (16%) | called by muse, mutect2, varscan2
- CRB2 | c.3348C>T p.F1116= | Silent (SNP) | VAF 20/135 reads (15%) | catalogued as COSV63502196; called by muse, mutect2, varscan2
- CREB3L2 | c.870A>T p.S290= | Silent (SNP) | VAF 10/184 reads (5%) | called by muse, mutect2
- CTBP2 | c.228C>T p.A76= | Silent (SNP) | VAF 28/171 reads (16%) | catalogued as rs201919800; called by muse, mutect2, varscan2
- CWF19L2 | c.1935T>C p.A645= | Silent (SNP) | VAF 13/133 reads (10%) | called by muse, mutect2, varscan2
- CYP26A1 | c.510C>T p.C170= | Silent (SNP) | VAF 69/396 reads (17%) | catalogued as rs778857066; called by muse, mutect2, varscan2
- DBN1 | c.345C>T p.I115= | Silent (SNP) | VAF 56/364 reads (15%) | catalogued as rs1281874649; called by muse, mutect2, varscan2
- DCUN1D1 | c.21G>A p.S7= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as rs754937408, COSV53043909; called by mutect2, varscan2
- DDX58 | c.1206G>A p.L402= | Silent (SNP) | VAF 7/116 reads (6%) | called by muse, mutect2
- DNHD1 | c.7488T>C p.P2496= | Silent (SNP) | VAF 67/497 reads (13%) | catalogued as rs982294975; called by muse, mutect2, varscan2
- DSP | c.5943T>C p.Y1981= | Silent (SNP) | VAF 40/319 reads (13%) | called by muse, mutect2, varscan2
- ECHS1 | c.462C>T p.A154= | Silent (SNP) | VAF 27/192 reads (14%) | catalogued as rs368985189; called by muse, mutect2, varscan2
- EGFR | c.117G>A p.T39= | Silent (SNP) | VAF 58/225 reads (26%) | catalogued as rs777186292, COSV99294694; called by muse, mutect2, varscan2
- FAM135A | c.2541T>C p.D847= (on ENST00000370479 / NM_001351599.1; = p.D634= on NM_020819.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 15/126 reads (12%) | called by muse, mutect2, varscan2
- FANCC | c.1161C>T p.C387= | Silent (SNP) | VAF 50/404 reads (12%) | catalogued as rs548998258, COSV56659902; ClinVar: likely benign; called by muse, mutect2, varscan2
- FASLG | c.369A>G p.T123= | Silent (SNP) | VAF 11/121 reads (9%) | called by muse, mutect2
- FAT1 | c.6879T>C p.S2293= | Silent (SNP) | VAF 45/345 reads (13%) | catalogued as rs1032218201; called by muse, mutect2, varscan2
- FLNC | c.5229G>A p.E1743= | Silent (SNP) | VAF 64/574 reads (11%) | catalogued as rs1245475286; called by muse, mutect2, varscan2
- FRMPD3 | c.4023C>G p.G1341= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV52188647; called by muse, mutect2, varscan2
- FUCA1 | c.46T>C p.L16= | Silent (SNP) | VAF 33/209 reads (16%) | called by muse, mutect2, varscan2
- GABBR1 | c.858G>A p.T286= | Silent (SNP) | VAF 11/131 reads (8%) | catalogued as rs374257753; called by muse, mutect2
- GALK1 | c.996G>A p.A332= | Silent (SNP) | VAF 105/774 reads (14%) | catalogued as rs1456156062, COSV52325479; called by muse, mutect2, varscan2
- GBP4 | c.978G>A p.L326= | Silent (SNP) | VAF 14/170 reads (8%) | catalogued as COSV100864286; called by muse, mutect2
- GEMIN8 | c.549C>T p.R183= | Silent (SNP) | VAF 51/371 reads (14%) | called by muse, mutect2, varscan2
- GK | c.744C>T p.S248= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs778331417, COSV66739676; called by mutect2, varscan2
- GNRH1 | c.195G>A p.T65= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as rs577363506, COSV52382614; called by muse, mutect2, varscan2
- GTF2A1 | c.831G>T p.G277= | Silent (SNP) | VAF 18/111 reads (16%) | catalogued as rs1162249371; called by muse, mutect2, varscan2
- H2BC17 | c.114C>T p.Y38= | Silent (SNP) | VAF 17/114 reads (15%) | catalogued as rs746284590, COSV58152048; called by muse, mutect2, varscan2
- HERC2 | c.9969G>A p.A3323= | Silent (SNP) | VAF 26/470 reads (6%) | catalogued as rs532645243, COSV55335825; called by muse, mutect2
- HIVEP2 | c.138G>T p.R46= | Silent (SNP) | VAF 34/309 reads (11%) | catalogued as rs760270683, COSV50053386; called by muse, mutect2, varscan2
- HMCN2 | c.10620C>T p.D3540= | Silent (SNP) | VAF 32/238 reads (13%) | catalogued as rs190602024; called by muse, mutect2, varscan2
- HOOK2 | c.1140C>T p.A380= | Silent (SNP) | VAF 12/226 reads (5%) | called by muse, mutect2
- HOXC10 | c.483G>A p.T161= | Silent (SNP) | VAF 25/284 reads (9%) | catalogued as rs781528101, COSV57726750; called by muse, mutect2
- HYI | c.570G>A p.T190= (on ENST00000372434 / NM_001330526.2; = p.T165= on NM_031207.6) | Silent (SNP) | VAF 41/283 reads (14%) | catalogued as rs139460802; called by muse, mutect2, varscan2
- IFFO1 | c.474G>A p.S158= | Silent (SNP) | VAF 33/71 reads (46%) | catalogued as rs1184567670; called by muse, mutect2, varscan2
- IFNA7 | c.315A>G p.L105= | Silent (SNP) | VAF 15/292 reads (5%) | called by muse, mutect2
- IRS1 | c.2439C>T p.S813= | Silent (SNP) | VAF 62/509 reads (12%) | catalogued as rs755294121, COSV59335559; called by muse, mutect2, varscan2
- JAK2 | c.2715A>G p.L905= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs971129534; called by mutect2, varscan2
- KHSRP | c.927C>T p.G309= | Silent (SNP) | VAF 31/283 reads (11%) | catalogued as rs369743548, COSV67919762; called by muse, mutect2, varscan2
- KIF5B | c.2298T>C p.H766= | Silent (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- KLHDC4 | c.669G>A p.P223= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as rs568401184, COSV99566267; called by muse, mutect2, varscan2
- KRT4 | c.609C>T p.G203= | Silent (SNP) | VAF 40/382 reads (10%) | called by muse, mutect2, varscan2
- LEO1 | c.456C>T p.D152= | Silent (SNP) | VAF 31/156 reads (20%) | called by muse, mutect2, varscan2
- LOXL2 | c.1785G>A p.R595= | Silent (SNP) | VAF 22/196 reads (11%) | called by muse, mutect2
- LOXL2 | c.1338C>T p.G446= | Silent (SNP) | VAF 15/225 reads (7%) | called by muse, mutect2
- LRRK1 | c.4077A>G p.G1359= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV52628992; called by muse, mutect2, varscan2
- MAGEC2 | c.309C>T p.C103= | Silent (SNP) | VAF 41/308 reads (13%) | called by muse, mutect2, varscan2
- MAGEL2 | c.2544G>A p.S848= | Silent (SNP) | VAF 33/228 reads (14%) | catalogued as rs758017131, COSV58566551, COSV58566765; called by muse, mutect2, varscan2
- MED15 | c.603A>G p.Q201= | Silent (SNP) | VAF 27/192 reads (14%) | called by muse, varscan2
- MRPL50 | c.9G>A p.A3= | Silent (SNP) | VAF 18/122 reads (15%) | called by muse, mutect2, varscan2
- MRTFB | c.1485T>C p.R495= | Silent (SNP) | VAF 47/336 reads (14%) | called by muse, mutect2, varscan2
- MTA1 | c.1482C>T p.H494= | Silent (SNP) | VAF 33/264 reads (13%) | catalogued as rs148954433; called by muse, mutect2, varscan2
- NAALADL2 | c.2029T>C p.L677= | Silent (SNP) | VAF 15/113 reads (13%) | called by muse, mutect2, varscan2
- NALCN | c.4618C>A p.R1540= | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as COSV51918025; called by muse, mutect2, varscan2
- NELFA | c.831C>T p.G277= (on ENST00000542778; = p.G266= on NM_005663.5) | Silent (SNP) | VAF 32/209 reads (15%) | catalogued as rs144909996; ClinVar: likely benign; called by muse, mutect2, varscan2
- NHSL2 | c.1059G>A p.S353= (on ENST00000510661; = p.S719= on NM_001013627.2) | Silent (SNP) | VAF 54/389 reads (14%) | catalogued as rs921664221; called by muse, mutect2, varscan2
- NME8 | c.1062G>A p.S354= | Silent (SNP) | VAF 55/266 reads (21%) | catalogued as rs148479667; called by muse, mutect2, varscan2
- NPBWR2 | c.219G>T p.A73= | Silent (SNP) | VAF 56/580 reads (10%) | catalogued as COSV63900054; called by muse, mutect2
- NSD1 | c.7032A>G p.S2344= | Silent (SNP) | VAF 52/325 reads (16%) | called by muse, mutect2, varscan2
- OBSCN | c.18699T>C p.S6233= | Silent (SNP) | VAF 34/207 reads (16%) | catalogued as rs373420411; called by muse, mutect2, varscan2
- OBSCN | c.23196C>T p.H7732= | Silent (SNP) | VAF 33/200 reads (17%) | catalogued as rs571437600; called by muse, mutect2, varscan2
- OR13A1 | c.702G>A p.A234= | Silent (SNP) | VAF 36/353 reads (10%) | catalogued as rs753962862, COSV65572856; called by muse, mutect2, varscan2
- OR4D11 | c.537C>T p.C179= | Silent (SNP) | VAF 45/409 reads (11%) | catalogued as rs374819635; called by muse, mutect2, varscan2
179 further variants in this file (0 protein-altering or splice-affecting, 65 silent, 114 other) are not listed here.
